ALCHEMIST case ALCH-B1YU — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/ddf83f31-57b3-4d97-b632-0d936be214fb

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 69.4 years (25,336 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B1YU-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B1YU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B1YU-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 40; Percent normal cells: 9; Percent necrosis: 0; Percent stromal cells: 8; Percent lymphocyte infiltration: 17; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
